CCDI case PBBUTU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/53654576-c6b2-4cff-8563-686e5b0779d1

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.2 years (1,184 days).

Biospecimens (2 samples)
- Sample 0DHV65: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHV6B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
